Gene-level copy-number profile of tumor specimen ALCH-B408-TTP1-A from ALCHEMIST case ALCH-B408, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma in situ, NOS; Age at diagnosis: 76.7 years (28,018 days).
Specimen ALCH-B408-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ff952339-f819-4266-83e8-e05a69aea425.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B408-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/489dcb25-37f0-4231-b6e0-8beb031c48ad

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 43; copy number 1: 334; copy number 2: 1,882; copy number 3: 16,728; copy number 4: 18,282; copy number 5: 7,862; copy number 6: 7,942; copy number 7: 2,586; copy number 8: 795; copy number 9: 1,740; copy number 10: 171; copy number 11: 9; copy number 12: 9; copy number 15: 1; copy number 17: 1; copy number 18: 2; copy number 23: 1; copy number 28: 1; copy number 84: 1.

Homozygous deletions (total copy number 0; autosomes only): 43 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,502,145–49,524,185, 4 genes: ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8.
- chr4:58,524,515–62,078,335, 22 genes (within-gene range 0–3): LINC02494, AC019133.1, AC017091.1, LINC02619, LINC02429, AC097501.1, AC108517.2, AC108517.1, Y_RNA, AC096588.1, AC093857.1, Y_RNA, RNU6-1325P, LINC02496, AC105420.1, MIR548AG1, LINC02271, ADGRL3, RPL17P19, AC020741.1, AC108161.1, Y_RNA.
- chr6:57,908,560–57,930,291, 2 genes: AL021368.2, GUSBP4.
- chr9:39,748,514–39,892,895, 6 genes: GLIDR, BX664615.1, BX664615.2, RN7SL763P, SNORA70, CR769767.1.
- chr9:63,581,254–63,581,834, 1 gene: AL591438.1.
- chr9:130,172,404–130,237,303, 1 gene: NCS1.
- chr16:2,131,851–2,136,129, 3 genes (within-gene range 0–5): Y_RNA, MIR4516, MIR3180-5.
- chr19:956,485–958,149, 1 gene (within-gene range 0–4): AC005391.1.
- chr19:20,443,215–20,443,725, 1 gene (within-gene range 0–1): BNIP3P23.
- chr19:43,211,791–43,269,530, 2 genes: CEACAMP10, PSG9.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,898 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:4,117,925–4,150,421, 3 genes, copy number 9: AC116562.1, OR7E103P, UNC93B4.
- chr4:57,030,773–57,207,459, 5 genes, copy number 10 (within-gene range 6–10): IGFBP7, UBE2CP3, IGFBP7-AS1, AC111197.1, AC105390.1.
- chr4:62,816,826–63,529,761, 4 genes, copy number 9: EXOC5P1, AC097491.1, LARP1BP1, AC093730.1.
- chr5:39,888,576–45,895,970, 88 genes, copy number 9 (broad region; genes not listed).
- chr8:47,089,572–143,878,467, 1,398 genes, copy number 9 (broad region; genes not listed).
- chr8:143,977,153–145,066,685, 76 genes, copy number 9 (broad region; genes not listed).
- chr9:40,105,822–40,333,460, 11 genes, copy number 9: AL773545.3, CDRT15P14, AL773545.1, AL773545.2, ANKRD20A2P, BX664727.3, RNU6-1269P, BX664727.2, SNX18P8, FAM95B1, BX664727.1.
- chr9:43,109,866–61,662,690, 19 genes, copy number 10–11: FP325317.1, FP325317.2, BX088702.1, SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1.
- chr9:64,878,790–64,889,063, 2 genes, copy number 18: AC125634.1, RNU6-1293P.
- chr11:1,947,278–1,989,920, 2 genes, copy number 17–84: MRPL23, MRPL23-AS1.
- chr15:32,359,538–32,367,784, 1 gene, copy number 28: AC139426.2.
- chr16:975,761–986,979, 2 genes, copy number 11 (within-gene range 5–11): CEROX1, SOX8.
- chr16:55,259,969–55,706,192, 14 genes, copy number 9 (within-gene range 6–9): AC109462.1, RN7SL841P, AC109462.3, IRX6, AC109462.2, RPL31P56, MMP2, AC007336.2, MMP2-AS1, AC007336.3, LPCAT2, AC007336.1, CAPNS2, SLC6A2.
- chr17:43,125,551–45,835,826, 153 genes, copy number 10 (within-gene range 6–10) (broad region; genes not listed).
- chr17:47,253,827–49,086,702, 99 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr21:44,107,373–44,131,181, 1 gene, copy number 23: PWP2.
- chr22:49,933,198–50,307,646, 20 genes, copy number 9–15: BX539320.1, PIM3, MIR6821, IL17REL, TTLL8, MLC1, MOV10L1, AL034546.1, PANX2, TRABD, AL022328.3, AL022328.4, SELENOO, AL022328.1, AL022328.2, TUBGCP6, HDAC10, MAPK12, MAPK11, PLXNB2.

Autosomal genes at a single copy (total copy number 1): 334. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
